Somatic mutation profile of tumor specimen TARGET-10-PARPNM-03A (aliquot TARGET-10-PARPNM-03A-01D) from TARGET case TARGET-10-PARPNM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,941 days).
Specimen TARGET-10-PARPNM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f3101cf-7274-4a78-aad7-1324d8e12349.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPNM-10A (Blood Derived Normal), aliquot TARGET-10-PARPNM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe8024fd-cdd9-44a0-a87a-f30a4a4c82c6

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Nonsense Mutation 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 55/206 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF28 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 20/233 reads (9%) | catalogued as rs758880284, COSV55261576; called by muse, mutect2
- CCDC60 | c.1223T>A p.L408H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59545183; called by muse, mutect2
- LOXL3 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs758529496, COSV51208670; called by muse, mutect2, varscan2
- MYH7 | c.4760A>G p.K1587R | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.12); catalogued as COSV62520210; called by muse, mutect2, varscan2
- SLC22A24 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 62/119 reads (52%) | catalogued as rs1310730794, COSV70301141, COSV70302700; called by muse, mutect2, varscan2
- SMG6 | c.4169C>T p.T1390M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183815005, COSV53964360; called by mutect2, varscan2
- WDR13 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV54332487; called by muse, varscan2
- PIGM | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PTPRM | c.2675T>G p.M892R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- THBS1 | c.2677G>T p.A893S | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2
- DNAH8 | c.4602A>C p.R1534= | Silent (SNP) | VAF 24/296 reads (8%) | catalogued as COSV59453632; called by muse, mutect2
- LRRC8C | c.762A>G p.E254= | Silent (SNP) | VAF 22/188 reads (12%) | catalogued as COSV64998747; called by muse, mutect2
- OR8D1 | c.150A>C p.A50= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV63442478; called by muse, mutect2
- PI4KA | c.4443G>A p.L1481= | Silent (SNP) | VAF 58/97 reads (60%) | catalogued as COSV55413535; called by muse, mutect2, varscan2
- PPIAL4G | c.81C>T p.D27= | Silent (SNP) | VAF 10/238 reads (4%) | catalogued as COSV101344003; called by muse, mutect2
- ZNF208 | c.732T>C p.L244= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV68108210; called by muse, mutect2
- AC024940.1 | n.4697A>G | RNA (SNP) | VAF 14/279 reads (5%) | called by muse, mutect2
- ARRDC1 | chr9:137616067 C>T | 3'Flank (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
